Somatic mutation profile of tumor specimen TCGA-EB-A5KH-06A (aliquot TCGA-EB-A5KH-06A-11D-A27K-08) from TCGA case TCGA-EB-A5KH, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 57.4 years (20,963 days).
Specimen TCGA-EB-A5KH-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 327bf216-2f59-4a09-94ad-61a1b2489b72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A5KH-10A (Blood Derived Normal), aliquot TCGA-EB-A5KH-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/281458c5-bbb5-432b-90ea-31748a6df00e

The open-access MAF lists 41 somatic variants for this specimen: 30 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 27, Silent 11, Frame Shift Ins 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.1924A>G p.K642E | Missense Mutation (SNP) | VAF 68/98 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913512, CM002803, COSV55387507, COSV55411978; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AKAP1 | c.2483G>A p.S828N | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as COSV61806114; called by muse, mutect2, varscan2
- APC | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 42/291 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as CD014918, COSV99967959; called by muse, mutect2, varscan2
- APLP1 | c.1646G>A p.R549Q (on ENST00000221891 / NM_001024807.3; = p.R548Q on NM_005166.4) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs368942763; called by muse, mutect2, varscan2
- C3 | c.2611G>A p.A871T | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.61); catalogued as COSV99836682; called by muse, mutect2, varscan2
- CXCR1 | c.120T>G p.Y40* | Nonsense Mutation (SNP) | VAF 41/107 reads (38%) | catalogued as COSV99826343; called by muse, mutect2, varscan2
- DDX4 | c.1407G>A p.M469I | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100737538; called by muse, mutect2, varscan2
- HMGXB4 | c.35G>A p.C12Y | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.079); catalogued as rs1450581806, COSV99330112; called by muse, mutect2, varscan2
- HNRNPCL1 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1370547609, COSV100509148, COSV58611111; called by muse, mutect2
- IHO1 | c.1722G>T p.K574N | Missense Mutation (SNP) | VAF 65/74 reads (88%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.571); catalogued as COSV99606196; called by muse, mutect2, varscan2
- KCNV1 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749043466, COSV52088536, COSV99819118; called by muse, mutect2, varscan2
- KNL1 | c.475C>A p.R159S (on ENST00000346991 / NM_170589.5; = p.R133S on NM_144508.5) | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100706525; called by muse, mutect2, varscan2
- MYO7B | c.2686G>A p.A896T | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as rs531750826, COSV67344143; called by muse, mutect2, varscan2
- MYSM1 | c.2290A>G p.I764V | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs1371696880, COSV101284047; called by muse, mutect2, varscan2
- NEBL | c.2398G>A p.V800I | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs367986765, COSV65802789; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEO1 | c.1713T>A p.N571K | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.284); catalogued as COSV99982118; called by muse, mutect2
- NTAN1 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV99816939; called by muse, mutect2, varscan2
- OR6B1 | c.418C>T p.L140F | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.082); catalogued as COSV101281652; called by muse, mutect2, varscan2
- PSMA6 | c.83C>G p.A28G | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99809188; called by muse, varscan2
- PXYLP1 | c.1193G>A p.R398K | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.145); catalogued as COSV99649482; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1476dup p.F493Vfs*6 | Frame Shift Ins (INS) | VAF 17/96 reads (18%) | catalogued as rs779171787; called by mutect2, pindel, varscan2
- SCN10A | c.194A>C p.K65T | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.145); catalogued as COSV101479264, COSV71860944, COSV71862775; called by muse, mutect2, varscan2
- SEC14L3 | c.1078G>A p.V360I | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs201231956; called by muse, mutect2, varscan2
- SLC4A8 | c.1265C>G p.P422R | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); catalogued as COSV100176933; called by muse, mutect2, varscan2
- TNFRSF21 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.273); catalogued as rs765519597, COSV57282739; called by muse, mutect2, varscan2
- TOP1MT | c.791T>C p.M264T | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as COSV100239430; called by muse, mutect2, varscan2
- UBE2K | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99787226; called by muse, mutect2, varscan2
- USP17L2 | c.1563C>G p.H521Q | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as rs1322595468, COSV100414601, COSV100414652; called by muse, mutect2, varscan2
- ZFAND1 | c.95T>A p.F32Y | Missense Mutation (SNP) | VAF 49/76 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99605432; called by muse, mutect2, varscan2
- SPRED1 | c.395dup p.N132Kfs*2 | Frame Shift Ins (INS) | VAF 10/13 reads (77%) | called by mutect2, varscan2
- DNAH2 | c.39C>G p.G13= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV99318216; called by muse, mutect2, varscan2
- ESS2 | c.861G>C p.L287= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs747507631, COSV99350914; called by muse, mutect2, varscan2
- HIC2 | c.1728C>G p.L576= | Silent (SNP) | VAF 24/246 reads (10%) | catalogued as COSV101335586; called by muse, varscan2
- IDH1 | c.825C>T p.D275= | Silent (SNP) | VAF 43/100 reads (43%) | catalogued as rs374900600; called by muse, mutect2, varscan2
- KCNJ4 | c.285G>A p.A95= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs758044908, COSV100341223; called by muse, mutect2, varscan2
- MRPS22 | c.330G>A p.L110= (on ENST00000310776 / NM_001363893.1; = p.L111= on NM_020191.4) | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as rs1163827490, COSV100169074; called by muse, mutect2, varscan2
- MYO15A | c.1047C>T p.Y349= | Silent (SNP) | VAF 59/117 reads (50%) | catalogued as rs567657743, CM115315, COSV99232936; ClinVar: likely benign; called by muse, mutect2, varscan2
- OCA2 | c.2436G>A p.L812= | Silent (SNP) | VAF 11/15 reads (73%) | catalogued as COSV100667923, COSV62360581; called by muse, mutect2, varscan2
- OR11H12 | c.777T>C p.H259= | Silent (SNP) | VAF 8/74 reads (11%) | called by mutect2, varscan2
- OR3A3 | c.414C>A p.P138= | Silent (SNP) | VAF 11/123 reads (9%) | catalogued as COSV99351374; called by muse, mutect2, varscan2
- ZNF234 | c.1785C>T p.P595= | Silent (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
